Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A8ML, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A8ML-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Patient Name
Med. Rec. #:
DOB:
Soc. Sec. #:
Physician(s):

Visit #: _____
Sex: male
Location: _____

Accession #: _____
Service Date: _____
Received: _____
Client: _____

FINAL PATHOLOGIC DIAGNOSIS

- A. Anterior prostatic fat, biopsy: Benign fibroadipose tissue, no tumor.
- B. Anterior urethral margin, biopsy: Benign skeletal muscle, no tumor.
- C. Lymph nodes, right pelvic, dissection: No tumor in five lymph nodes (0/5).
- D. Anterior bladder neck, biopsy:
1. Benign fibromuscular tissue; no tumor.
2. One benign lymph node (0/1).
- E. Lymph nodes, left pelvic, dissection: No tumor in six lymph nodes (0/6).
- F. Prostate and seminal vesicles, prostatectomy:
1. Prostatic adenocarcinoma, Gleason grade 3+4 = 7, involving bilateral lobes, margins negative; see comment.
2. Benign seminal vesicles.

COMMENT:

Synoptic Comment for Prostate Tumors

- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:** Left posterior apex, slide F9; left posterior mid gland, slide F10; left posterior base, slide F11; left anterior apex, slide F12; left anterior mid gland, slide F13; left anterior base, slide F14; right posterior apex, slide F6; right posterior mid gland, slide F7; right posterior base, slide F8; right anterior apex, slide F3; right anterior mid gland, slide F4; right anterior base, slide F5.
- **Estimated volume of tumor:** 0.96 ml.
- **Gleason score:** 3+4; primary pattern 3, secondary pattern 4.
- **Estimated volume > Gleason pattern 3:** 5-10%.
- **Involvement of capsule:** None.

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JW 1/28/14

[page 2 of 4]
- **Extraprostatic extension:** None.
- **Margin status for tumor:** Negative.
- **Margin status for benign prostate glands:** Benign glands present at inked excision margins; right and left bladder margins, slides F15 and F16.
- **High-grade prostatic intraepithelial neoplasia (HGPIN):** None.
- **Tumor involvement of seminal vesicle:** None.
- **Perineural infiltration:** Present (slide F7).
- **Lymph node status:** Negative; total number of nodes examined: 12; all tissue from Parts C and E (designated right and left pelvic lymph nodes, respectively) was submitted for microscopic evaluation.
- **AJCC/UICC stage:** pT2cN0.

Specimen(s) Received

A: Anterior prostatic fat
B: Anterior urethral margin
C: Right pelvic lymph nodes
D: Anterior bladder neck
E: Left pelvic lymph nodes
F: Prostate + seminal vesicles (fresh)

Clinical History

The patient is a [redacted] man with prostatic adenocarcinoma. Biopsy reviewed here ([redacted]) showed adenocarcinoma present in the left apex (Gleason grade 3+4), left mid (4+3), left base (3+3), right apex (3+4) and right mid (3+3). He now undergoes robotic-assisted laparoscopic prostatectomy with pelvic lymph node dissections.

Gross Description

The specimen is received in five parts, each labeled with the patient's name and medical record number. Parts A-E are received in formalin and part F is received fresh.

Part A, additionally labeled "anterior prostatic fat," consists of two pieces of irregular, unoriented, yellow fibrofatty tissue (1.3 x 1.2 x 0.2 cm and 0.9 x 0.5 x 0.2 cm) without firm areas. The specimen is entirely submitted in cassette A1. [redacted]

Part B, additionally labeled "anterior urethral margin," consists of and irregular, unoriented white-tan, firm tissue fragment (0.8 x 0.7 x 0.4 cm). The specimen is inked blue, trisected and entirely submitted in cassette B1. [redacted]

Part C, additionally labeled "right pelvic lymph nodes," consists of an irregular, unoriented, yellow-tan fibrofatty tissue (5 x 3 x 0.8 cm) that contains one pink-tan lymph node (4.1 x 0.6 x 0.6 cm). The lymph node is trisected. The cut surface of the lymph node appears homogeneous, pink-tan and smooth. The specimen is entirely submitted as follows:

Cassette C1: Lymph node.
Cassette C2: Lymph node and fibrofatty tissue.
Cassette C3: Fibrofatty tissue. [redacted]

Part D, additionally labeled "anterior bladder neck," consists of an irregular, unoriented, tan-brown, firm tissue fragment (1.5 x 1 x 0.5 cm). The roughened surface is inked blue and the smooth surface is inked green. The specimen is serially sectioned and entirely submitted in cassette D1. [redacted]

Part E, additionally labeled "left pelvic lymph node," consists of multiple pieces of irregular, unoriented yellow-tan fragmented fibrofatty tissue (5 x 4 x 0.8 cm in aggregate) that contain two uniform, pink-tan lymph nodes (3.5 cm and 1 cm in greatest dimension respectively). The cut surface of the larger lymph node appears homogeneous, tan-yellow and smooth. The specimen is entirely submitted as follows:

Cassettes E1-E2: Larger lymph node, serially sectioned.
Cassette E3: Intact smaller lymph node and fibrofatty tissue.
Cassettes E4-E5: Remaining fibrofatty tissue. [redacted]

[page 3 of 4]
Part F, additionally labeled "prostate and seminal vesicles," consists of a radical prostatectomy specimen (45 gm; 4 cm from apex to base x 4 cm in width x 3 cm from anterior to posterior).

GROSS PATHOLOGIC FINDINGS: There are multiple tan, rubbery nodules (largest 1.1 x 1 x 0.8 cm) located centrally. In slices 1-2, there is an irregular, white-tan, firm area (0.7 x 0.6 x 0.6 cm) in the left anterior peripheral aspect that does not extend across the midline, located 0.1 cm from the left lateral margin. In slices 4-5, two irregular white-tan, firm areas are identified. The larger white-tan, firm area (1.3 x 0.6 x 0.5 cm) is present in the right lateral peripheral aspect that does not extend across the midline, and is 0.1 cm from the right posterior-lateral margin. The smaller white-tan firm area (1.1 x 0.5 x 0.3 cm) is present in the left posterior peripheral aspect that does not extend across the midline, located 0.1 cm from the left posterior-lateral margin.

The anterior fibrous stroma is red-tan, roughened and is tightly suture closed. The remaining capsule is intact. The remaining prostatic parenchyma is tan. The seminal vesicle/vas deferens bundles (right 5 x 2.5 x 1 cm; left 4.5 x 2.5 x 0.8 cm) are soft, lobulated, red-tan without obvious lesion or mass. Some of the prostate tissue is taken by the tissue core. The un-sectioned slices are embedded for research purposes. The specimen is searched extensively for candidate lymph nodes and none are found.

ORIENTED BY: Anatomic landmarks - seminal vesicles, urethra.

INKING:

- Right anterior: Green.
- Left anterior: Blue.
- Posterior: Black.

POTENTIAL STUDIES:

GROSS PHOTOGRAPHS: Yes.

TOTAL NUMBER OF SLICES: (not including apex and base margin slices) eight.

AVERAGE SLICE THICKNESS: 0.4 cm.

CASSETTES: Representative sections are submitted as follows:

Apical margins, entirely submitted in perpendicular sections

F1: Right apex.

F2: Left apex.

Right anterior quadrant

F3: Slice 2.

F4: Slice 4, with largest nodule located centrally and a portion of the 1.3 cm white-tan, firm area.

F5: Slice 6.

Right posterior quadrant

F6: Slice 2.

F7: Slice 4, with larger portion of the 1.3 cm white-tan, firm area.

F8: Slice 6.

Left posterior quadrant

F9: Slice 2.

F10: Slice 4, with 1.1 cm white-tan, firm area.

F11: Slice 6.

Left anterior quadrant

F12: Slice 2, with 0.7 cm white-tan firm area.

F13: Slice 4.

F14: Slice 6.

Bladder margins, entirely submitted in perpendicular sections

F15: Right.

F16: Left.

Prostatic/seminal vesicle junction and cross-section of vas deferens

F17: Right.

F18: Left.

[page 4 of 4]
Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Electronically signed out

Source: NCI Genomic Data Commons file 9312a856-0b53-41a6-8773-35f3ec973710 (TCGA-V1-A8ML.4C4405A3-FC07-4155-8C5A-2693E34F347B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).